Somatic mutation profile of tumor specimen BLGSP-71-06-00340-01A (aliquot BLGSP-71-06-00340-01A-01D-A663-33) from CGCI case BLGSP-71-06-00340, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS.
Specimen BLGSP-71-06-00340-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Abdomen; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e2874a6-4f72-4989-b620-b9923fa3ba17.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-06-00340-12A (Buccal Cell Normal), aliquot BLGSP-71-06-00340-12A-01D-A663-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/907e2ba1-17fc-4ea6-ba90-e806aba8c7b0

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Splice Site 2, Frame Shift Del 2, 5'Flank 2, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TBL1XR1 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 64/274 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); catalogued as rs1057517933, CM162314, COSV70501537; ClinVar: pathogenic; called by muse, varscan2
- ARID1A | c.3406+1G>T p.X1136_splice | Splice Site (SNP) | VAF 55/116 reads (47%) | catalogued as COSV61374750; called by muse, mutect2, varscan2
- B2M | c.45_48del p.S16Afs*27 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as COSV62562863; called by pindel, varscan2
- ID3 | c.300+1G>T p.X100_splice | Splice Site (SNP) | VAF 23/55 reads (42%) | catalogued as COSV65801120; called by muse, mutect2, varscan2
- ID3 | c.300G>A p.Q100= | Splice Region (SNP) | VAF 23/53 reads (43%) | catalogued as COSV104424113, COSV65801413; called by muse, mutect2, varscan2
- TBL1XR1 | c.1057A>C p.N353H | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101467746; called by muse, varscan2
- TCL1A | c.113C>G p.T38S | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs201228671, COSV68085105, COSV68085114, COSV68085683; called by muse, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 27/51 reads (53%) | called by pindel, varscan2
- DDX3X | c.1604G>T p.G535V (on ENST00000399959; = p.G536V on NM_001356.5) | Missense Mutation (SNP) | VAF 32/698 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TACC2 | c.7349C>A p.P2450H (on ENST00000334433; = p.P528H on NM_006997.4) | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- TCL1A | c.98C>G p.A33G | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, varscan2
- H1-4 | c.324C>T p.N108= | Silent (SNP) | VAF 57/62 reads (92%) | catalogued as rs138100908; called by muse, mutect2, varscan2
- MYC | c.18C>T p.S6= (on ENST00000377970; = p.S21= on NM_002467.6) | Silent (SNP) | VAF 128/324 reads (40%) | catalogued as rs772792914, COSV52367888, COSV52373284; called by muse, varscan2
- MYC | c.163C>T p.L55= (on ENST00000377970; = p.L70= on NM_002467.6) | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as COSV52368833; called by muse, varscan2
- MYC | c.444G>A p.K148= (on ENST00000377970; = p.K163= on NM_002467.6) | Silent (SNP) | VAF 52/139 reads (37%) | called by muse, varscan2
- AC072022.2 | c.-56C>T | 5'UTR (SNP) | VAF 20/53 reads (38%) | catalogued as rs929797612, COSV69204172; called by muse, mutect2, varscan2
- TMSB4X | chrX:12975616 C>T | 5'Flank (SNP) | VAF 18/38 reads (47%) | catalogued as COSV66082159; called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58332104 T>C | 5'Flank (SNP) | VAF 86/188 reads (46%) | called by muse, mutect2, varscan2
